Surgical pathology report (de-identified scan), TCGA case TCGA-IQ-A6SG, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University of Miami, specimen TCGA-IQ-A6SG-01A (Primary Tumor).

[page 1 of 7]
Surgical Pathology Report

Name: XXXX
DOB:
Gender: F
MRN: XX
Location: X
Physician: XX

Case #: XXX
Collected:
Received:
Reported:

Pathologic Interpretation:

A. RIGHT SIDED SUBMENTAL LYMPH NODE:

No malignancy seen in one lymph node (0/1).

B. DISTAL LEFT LINGUAL NERVE:

No malignancy seen.

C. REAL DISTAL LINGUAL NERVE:

No malignancy seen.

D. LEFT HYPOGLOSSAL PROXIMAL NERVE:

No malignancy seen.

E. RIGHT LINGUAL ARTERY:

No malignancy seen.

F. SUBTOTAL GLOSSECTOMY WITH LEFT LEVEL 1 NECK DISSECTION:

INVASIVE MODERATELY DIFFERENTIATED KERATINIZING SQUAMOUS CELL CARCINOMA, 5.2 cm, of the tongue.

The tumor extends to the deep left lateral margin of the specimen (see note).

Perineural invasion is not present.

No malignancy seen in eleven lymph nodes (0/11).

Note: True surgical margins are best represented by frozen section specimens.

G. ANTERIOR RIGHT TONGUE REMNANT MARGIN:

No malignancy seen.

ICD-O-3
Carcinoma, squamous cell
keratinizing NOS 8071/3
Site Tongue NOS C02.9
path
Overlapping lesion of
Tongue C02.8
Jed 7/23/13

[page 2 of 7]
H. CENTRAL DORSAL TONGUE:

No malignancy seen.

I. RIGHT ANTERIOR FLOOR OF MOUTH, CLIP POSTERIOR:

No malignancy seen.

J. BASE OF TONGUE, CLIP LEFT VALLECULA:

No malignancy seen.

K. LEFT RETROMOLAR TRIGONE:

No malignancy seen.

L. LEFT PHARYNGEAL MUCOSA RESECTION MARGIN, CLIP SUPERIOR:

No malignancy seen.

M. DEEP TONGUE MARGIN:

No malignancy seen.

N. DEEP MARGIN TONGUE ANTERIOR:

No malignancy seen.

O. DEEP FLOOR OF MOUTH MUSCLE:

No malignancy seen.

P. ALVEOLAR RIDGE MARGIN, CLIP ANTERIOR:

No malignancy seen.

Q. LEFT PERI-FACIAL LYMPH NODE:

No malignancy seen.

R. ADDITIONAL RESECTION ALVEOLAR RIDGE:

No malignancy seen.

S. RIGHT FACIAL NERVE:

No malignancy seen, one lymph node (0/1).

[page 3 of 7]
T. ADDITIONAL RIGHT ALVEOLAR RIDGE MUCOSA:

No malignancy seen.

U. LEFT FACIAL ARTERY BRANCH:

No malignancy seen.

V. RIGHT LEVEL 1 NECK DISSECTION:

No malignancy seen in five lymph nodes (0/5) and salivary gland tissue.

W. LEVEL 2-4 NECK DISSECTION, STITCH AT LEVEL 2:

No malignancy seen in twenty-seven lymph nodes (0/27).

X. LEFT TONSIL:

No malignancy seen.

Y. SUBMENTAL NECK DISSECTION:

No malignancy seen in one lymph node (0/1).

Z. RIGHT NECK DISSECTION LEVEL 2-4:

No malignancy seen in twenty-three lymph nodes (0/23).

AA. RIGHT NECK DISSECTION LEVEL 2B:

No malignancy seen in two lymph nodes (0/2).

AB. FAILED FREE FLAP:

No malignancy seen.

AC. TIP OF TONGUE:

Squamous mucosa with keratosis.

Surgical Pathology Cancer Case Summary

Specimen:

Ventral surface of tongue, not otherwise specified (NOS)

Dorsal surface of tongue, NOS

Received: Fresh

Procedure:

Resection

Glossectomy (specify): Subtotal glossectomy

Neck (lymph node) dissection: Right and left

Specimen Integrity: Intact

Specimen Size:

[page 4 of 7]
Greatest dimensions: 7.0 x 6.0 x 4.0 cm
Specimen Laterality: Bilateral
Tumor Site:
Ventral surface of tongue, NOS
Dorsal surface of tongue, NOS
Tumor Focality: Single focus
Tumor Size:
Greatest dimension: 5.2 cm
Additional dimensions: 5.0 x 3.0 cm
Tumor Description: Ulcerated
Histologic Type: Squamous cell carcinoma, conventional
Histologic Grade:
G2: Moderately differentiated
Margins:
Margins uninvolved by invasive carcinoma
Lymph-Vascular Invasion: Not identified
Perineural Invasion: Not identified
Pathologic Staging (pTNM):
Primary Tumor (pT):
pT3: Tumor more than 4 cm in greatest dimension
Regional Lymph Nodes (pN):
pN0: No regional lymph node metastasis
Number of Lymph Nodes Examined: Seventy-one (71)
Number of Lymph Nodes Involved: Zero (0)
Distant Metastasis (pM):
Not applicable

X>

Electronically Signed Out By

Intraoperative Consultation:

- A. RIGHT SIDED SUBMENTAL LYMPH NODE, FS: Lymph node, no tumor seen.
- B. DISTAL LEFT LINGUAL NERVE, FS: No tumor seen.
- C. REAL DISTAL LINGUAL NERVE, FS: No tumor seen.
- D. LEFT HYPOGLOSSAL PROXIMAL NERVE, FS: No tumor seen.
- E. RIGHT LINGUAL ARTERY, FS: No tumor seen.
- G. ANTERIOR RIGHT TONGUE REMNANT MARGIN, FS: No tumor seen.
- H. CENTRAL DORSAL TONGUE, FS: No tumor seen.
- I. RIGHT ANTERIOR FLOOR OF MOUTH, CLIP POSTERIOR, FS: No tumor seen.
- J. BASE OF TONGUE, CLIP LEFT VALLECULA, FS: No tumor seen.
- K. LEFT RETROMOLAR TRIGONE, FS: No tumor seen.
- L. LEFT PHARYNGEAL MUCOSA RESECTION MARGIN, CLIP SUPERIOR, FS: No tumor seen.
- M. DEEP TONGUE MARGIN, FS: No tumor seen.
- N. DEEP MARGIN TONGUE ANTERIOR, FS: No tumor seen.
- O. DEEP FLOOR OF MOUTH MUSCLE, FS: No tumor seen.

[page 6 of 7]
Gross Description:

A. Received fresh labeled "Right sided submental lymph node, FS" is a 0.6 x 0.5 x 0.4 cm lymph node. It is bisected and submitted in toto in one cassette for frozen section.

B. Received fresh labeled "Distal left lingual nerve, FS" is a 0.6 x 0.3 x 0.3 cm soft tissue fragment. It is submitted in toto in one cassette for frozen section.

C. Received fresh labeled "Real distal lingual nerve, FS" is a 0.9 x 0.3 x 0.2 cm elongated soft tissue fragment. It is submitted in toto in one cassette for frozen section.

D. Received fresh labeled "Left hypoglossal proximal nerve, FS" is a 0.5 x 0.4 x 0.3 cm soft tissue. It is submitted in toto in one cassette for frozen section.

E. Received fresh labeled "Right lingual artery, FS" is a 0.7 x 0.3 x 0.2 cm tan-gray soft tissue. It is submitted in toto in one cassette for frozen section.

F. Received fresh labeled "Subtotal glossectomy with left level 1 neck dissection, stitch left base of tongue" is a composite resection of portion of tongue, along with portion of salivary gland and Level 1 lymph nodes. The tongue is oriented with a stitch at the left base. The tongue measures 7 x 6 x 4 cm. The salivary gland measures 3.3 x 2.0 x 1.0 cm. The lymph nodes (Level 1) measure in aggregate, 6 x 4 x 3 cm. On the dorsal surface of the tongue, there is an ulcerated area measuring approximately 4 x 3 cm. The ulcerated area continues with a tan-white irregular firm mass and the mass appears to be present at the inked deeper surface of the tongue. For orientation purposes, the specimen inked as follows: superior surface inked black, inferior surface inked blue, left lateral surface inked green, right lateral surface inked orange and anterior surface inked yellow. Upon serial sectioning, there is an oval, well defined tan-white firm mass occupying 90% of the tongue and underlying floor of the mouth measuring approximately 5.2 x 5.0 x 3.0 cm. The mass is approximately at the left lateral margin, 1.0 cm away from the anterior margin, appears to be present at the inked inferior resection margin. It is present approximately 0.2 cm away from the superior margin and 0.2 cm away from the right lateral margin. The mass grossly does not involve the adjacent salivary gland. The salivary gland is tan-yellow to white, lobulated soft with no gross lesions. Serial sectioning of the Level 1 adipose tissue shows multiple possible lymph nodes ranging from 0.3 cm to 1.3 cm. A representative section of the tumor measuring 1.0 x 0.3 x 0.3 cm is taken for the Tissue Bank. Sections are submitted as follows:

Cassette #1	Mass in relation to the right lateral margin
Cassette #2	Mass in relation to the left lateral margin near the base
Cassette #3	Mass in relation to the anterior margin
Cassette #4	Mass in relation to the posterior margin
Cassette #5	Mass in relation to the superior surface
Cassette #6	Mass in relation to the inferior surface
Cassette #7	Mass in relation to adjacent normal tongue
Cassette #8	Normal salivary gland
Cassettes 9&10	One largest lymph node bisected
Cassette #11	One lymph node bisected
Cassette #12	One lymph node bisected
Cassettes #13-17	Adipose tissue fragments for multiple possible lymph nodes

G. Received fresh labeled "Anterior right tongue remnant margin, FS" is a 10.5 x 1.0 x 0.5 cm tan-white to brown soft specimen. It is serially sectioned and submitted in toto in three cassettes for frozen section.

H. Received fresh labeled "Central dorsal tongue, FS" is a 4.5 x 1.2 x 0.4 cm tan-brown soft tongue. It is submitted in toto in one cassette for frozen section.

I. Received fresh labeled "Right anterior floor of mouth, clip posterior, FS" is a 2.2 x 0.5 x 0.4 cm tan-white soft tissue with a clip. The area near the clip inked black. It is submitted in toto in one cassette for frozen section.

J. Received fresh labeled "Base of tongue, clip left vallecula, FS" is a 6.0 x 0.7 x 0.3 cm tan-white soft tissue with a clip. The area near the clip inked black. It is submitted in toto in one cassette.

K. Received fresh labeled "Left retromolar trigone, FS" is a 1.5 x 0.5 x 0.4 cm tan-white soft tissue. It is submitted in toto in one cassette for frozen section.

L. Received fresh labeled "Left pharyngeal mucosa resection margin, clip superior, FS" is a 7.2 x 0.8 x 0.2 cm with a clip. The area near the clip inked black. It is serially sectioned and submitted in toto in one cassette.

M. Received fresh labeled "Deep tongue margin, FS" is a 1.8 x 1.3 x 0.3 cm tan-white soft tissue. It is submitted in toto in one cassette.

N. Received fresh labeled "Deep margin tongue anterior, FS" is a 1.5 x 1.0 x 0.7 cm tan-white soft tissue. It is submitted in toto in one cassette for frozen section.

O. Received fresh labeled "Deep floor of mouth muscle, FS" is a 1.5 x 0.7 x 0.5 cm tan-white soft tissue. It is submitted in toto in one cassette for frozen section.

P. Received fresh labeled "Alveolar ridge margin, clip anterior, FS" is a 4.5 x 0.4 x 0.4 cm tan-white soft tissue with a clip. The area near the clip inked black. It is submitted in toto in one cassette.

[page 7 of 7]
Q. Received in formalin labeled "Left peri-facial lymph node" is a 1.0 x 1.0 x 0.3 cm pale yellow soft lymph node. It is submitted in toto in one cassette.

R. Received in formalin labeled "Additional resection alveolar ridge" is a 6.0 x 0.3 x 0.3 cm pale tan, white soft tissue. It is submitted in toto in one cassette.

S. Received in formalin labeled "Right facial nerve" is a 1.2 x 1.0 x 0.3 cm pale tan white soft tissue. It is submitted in toto in one cassette.

T. Received in formalin labeled "Additional right alveolar ridge mucosa" is a 1.2 x 0.3 x 0.3 cm pale tan white soft tissue. It is submitted in toto in one cassette.

U. Received in formalin labeled "Left facial artery branch" is a calcified structure measuring approximately 0.5 x 0.2 x 0.2 cm. It is submitted in toto in one cassette.

V. Received in formalin labeled "Right Level 1 neck dissection" is a portion of salivary gland measuring 3 x 2 x 2 cm with an attached adipose tissue measuring 3 x 3 x 3 cm. The salivary gland is yellow lobulated, tan-white with no gross lesions. Serial sectioning of the adipose tissue reveals six possible lymph nodes ranging from 0.8 to 1.3 cm. Sections are submitted as follows:

- Cassette #1 Salivary gland tissue
- Cassettes #2&3 Two lymph nodes in each cassette
- Cassette #4: One lymph node

W. Received in formalin labeled "Level 2-4 neck dissection, stitch at level 2" is a 12 x 3 x 2 cm pale yellow soft adipose tissue with a stitch at one end designated as Level 2. Serial sectioning reveals multiple possible lymph nodes ranging from 0.2 to largest, 2.5 cm. Sections are submitted as follows:

- Cassette #1 Largest lymph node at Level 2, bisected
- Cassette #2 Four lymph nodes at Level 2
- Cassette #3 Four lymph nodes at Level 2
- Cassettes #4&5 Largest lymph node at Level 3, bisected
- Cassette #6 One lymph node at level 3, bisected
- Cassette #7 One lymph node, bisected in each from Level 3
- Cassette #8 Three lymph nodes from Level 3
- Cassette #9 Four lymph nodes from Level 4
- Cassette #10 Three lymph nodes from Level 4
- Cassette #11 Five lymph nodes from Level 4

X. Received in formalin labeled "Left tonsil" is a 3 x 2 x 1 cm pale tan, yellow to brown soft tissue. It is serially sectioned. No gross lesions are identified. Representative sections are submitted in one cassette.

Y. Received in formalin labeled "Submental neck dissection" is a 5 x 3 x 2 cm pale yellow soft adipose tissue. Serial sectioning reveals two lymph nodes ranging from 0.9 to 1.0 cm. Sections are submitted as follows:

- Cassette #1 Two lymph nodes
- Cassette #2 Representative section of adipose tissue for more possible lymph nodes

Z. Received in formalin labeled "Right neck dissection level 2-4" is an 8 x 3 x 2 cm pale yellow soft adipose tissue fragment with a stitch at one end representing Level 2. Serial sectioning reveals multiple possible lymph nodes ranging from 0.5 to 1.3 cm. Sections are submitted as follows:

- Cassette #1 Three lymph nodes at Level 2
- Cassette #2 Two lymph nodes at Level 2
- Cassette #3 Two lymph nodes at Level 2
- Cassette #4 Four lymph nodes from Level 3
- Cassettes #5&6 Three lymph nodes in each from Level 3
- Cassette #7 Three lymph nodes from Level 4
- Cassette #8 Four lymph nodes from Level 4

AA. Received in formalin labeled "Right neck dissection level 2B" is a 3 x 2 x 2 cm pale yellow soft adipose tissue. Serial sectioning reveals three possible lymph nodes ranging from 0.2 to 1.3 cm. Three lymph nodes are submitted in toto in one cassette.

AB. Received in formalin labeled "Failed free flap" is an ellipse of skin measuring approximately 13 x 7 cm. It is 3.5 cm in thickness. The skin is tan-white smooth and soft with no gross lesions. The adipose tissue is pale yellow and lobulated. Serial sectioning does not reveal any gross lesions. There is an attached fragment of skeletal muscle measuring 4 x 2 x 2 cm. It is tan-brown and soft with no gross lesions. Representative sections are submitted in one cassette.

AC. Received in formalin labeled "Tip of tongue" is a 4 x 1 x 1 cm pale soft round fragment of tongue. It is bisected and submitted in toto in one cassette.

XX,

Final Malignancy History		
Qual/Synchronously Biopsied		

Source: NCI Genomic Data Commons file bb07324d-2329-4534-a667-85d0ad2a0afc (TCGA-IQ-A6SG.4BC55A0C-F136-40F3-85AE-B530A2F4943D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).